CCDI case PBCAMB — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/b3b43f9a-5b02-495e-9f03-3ac3494ff572

Demographics
Sex at birth: female; Race: white; Vital status: Alive.

Diagnoses (1)
1. Pilocytic astrocytoma: ICD-O-3 morphology code: 9421/1; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 15.4 years (5,641 days).

Biospecimens (3 samples)
- Sample 0DN1AZ: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DN1BN: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DN1D7: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
